Somatic mutation profile of tumor specimen 0DT3UB from CCDI case PBCHTT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.4 years (882 days).
Specimen 0DT3UB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0dcfbea-fde3-4fd4-be3f-cbe9039e4c7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT3UN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68ad995b-9073-4243-b005-4b02612d8b29

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 3, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 217/590 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LMBR1L | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 177/849 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs541298805, COSV57267548; called by muse, mutect2, varscan2
- SYTL5 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 227/307 reads (74%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as COSV99936897; called by muse, mutect2, varscan2
- AGAP1 | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 92/652 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT6B | c.578T>C p.I193T | Missense Mutation (SNP) | VAF 281/747 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- DCHS1 | c.3307C>A p.P1103T | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMB4 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 235/698 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPCAT1 | c.989dup p.C330Wfs*20 | Frame Shift Ins (INS) | VAF 192/742 reads (26%) | called by mutect2, varscan2
- MARK3 | c.2182G>T p.V728F (on ENST00000429436 / NM_001128918.3; = p.V704F on NM_002376.6) | Missense Mutation (SNP) | VAF 214/1219 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP13 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 163/786 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ZC3H4 | c.852_866del p.F284_M289delinsL | In Frame Del (DEL) | VAF 72/564 reads (13%) | called by mutect2, varscan2
- ZNF687 | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 157/757 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ADGRB1 | c.3951C>G p.S1317= | Silent (SNP) | VAF 254/901 reads (28%) | catalogued as COSV60094286, COSV60101885; called by muse, mutect2, varscan2
- PDGFRA | c.21G>T p.A7= | Silent (SNP) | VAF 194/532 reads (36%) | catalogued as COSV99955876; called by mutect2, varscan2
- PTPN22 | c.1611T>C p.F537= (on ENST00000359785 / NM_001193431.2; = p.F482= on NM_012411.5) | Silent (SNP) | VAF 231/1333 reads (17%) | called by muse, mutect2, varscan2
- TSHZ3 | c.810C>T p.D270= | Silent (SNP) | VAF 152/839 reads (18%) | catalogued as rs775613015, COSV53666834; called by muse, mutect2, varscan2
- FYB1 | c.2264-85T>C | Intron (SNP) | VAF 63/236 reads (27%) | catalogued as rs1309787327; called by muse, mutect2, varscan2
- KATNAL2 | c.-23C>G | 5'UTR (SNP) | VAF 125/198 reads (63%) | catalogued as rs759143923; called by muse, mutect2, varscan2
- SLC35F2 | c.110+109G>C | Intron (SNP) | VAF 90/326 reads (28%) | called by muse, mutect2, varscan2
- SUSD2 | c.77-36C>G | Intron (SNP) | VAF 40/122 reads (33%) | called by muse, mutect2, varscan2
